CCDI case PBBPNV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/354bd3b4-c8d3-4a0b-9035-d6e008763765

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.8 years (3,576 days).

Biospecimens (2 samples)
- Sample 0DHV67: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DHV6E: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
